Gene-level copy-number profile of tumor specimen TCGA-02-0014-01A from TCGA case TCGA-02-0014, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.7 years (9,369 days).
Specimen TCGA-02-0014-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.bf7821ea-0647-48a9-afff-e383e859d41d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0014-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4c60719c-f158-4d65-9ab2-226d4b0f53b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 9,061; copy number 2: 45,558; copy number 3: 4,310; copy number 4: 353; copy number 5: 94; copy number 6: 45; copy number 7: 33; copy number 8: 138; copy number 9: 14; copy number 10: 48; copy number 11: 86; copy number 15: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0014-01): tumor purity 0.95, ploidy 2.01, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,186,694–24,905,735, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 462 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,364,630–23,015,852, 14 genes, copy number 9: AL591122.1, ZBTB40, ZBTB40-IT1, EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253, LACTBL1, TEX46.
- chr1:156,212,982–156,511,681, 17 genes, copy number 6: PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1.
- chr1:167,630,093–168,075,843, 8 genes, copy number 6 (within-gene range 3–6): RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2.
- chr2:9,936,360–20,861,661, 171 genes, copy number 7–8 (broad region; genes not listed).
- chr4:49,588,772–57,658,800, 124 genes, copy number 5–11 (broad region; genes not listed).
- chr4:187,746,094–190,092,279, 51 genes, copy number 5: ADAM20P3, AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr8:107,857,589–108,132,114, 5 genes, copy number 5: AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1.
- chr10:121,133,090–121,598,458, 4 genes, copy number 15: RPL19P16, LINC01153, RN7SKP167, FGFR2.
- chr11:85,852,557–89,301,477, 68 genes, copy number 6–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,668. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
